Somatic mutation profile of tumor specimen TCGA-XF-A9SM-01A (aliquot TCGA-XF-A9SM-01A-11D-A42E-08) from TCGA case TCGA-XF-A9SM, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 76.2 years (27,826 days).
Specimen TCGA-XF-A9SM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ab7b48d-476b-4371-bc0b-cd59c8fd3aa6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9SM-10A (Blood Derived Normal), aliquot TCGA-XF-A9SM-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cef30fa8-e85d-4781-bab9-5ad335d5ba7b

The open-access MAF lists 238 somatic variants for this specimen: 169 protein-altering or splice-affecting, 63 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 151, Silent 63, Nonsense Mutation 14, Frame Shift Del 2, Intron 2, Splice Region 1, 3'Flank 1, 5'UTR 1, Splice Site 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 51/174 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.446C>G p.S149* | Nonsense Mutation (SNP) | VAF 32/161 reads (20%) | catalogued as rs587778870, COSV57325898, COSV99927130; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV54033095; called by muse, mutect2
- AC100868.1 | c.1288G>C p.D430H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV51846240; called by muse, mutect2, varscan2
- ACSS3 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.106); catalogued as rs914039814, COSV54089066; called by muse, mutect2, varscan2
- ADCY5 | c.3043G>C p.D1015H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100568098, COSV59193958, COSV59200585; called by muse, mutect2, varscan2
- ADD1 | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99297156; called by muse, mutect2, varscan2
- AHDC1 | c.2734C>T p.Q912* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99899815; called by muse, mutect2, varscan2
- AHNAK | c.5629G>A p.V1877M | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as COSV57210502; called by muse, mutect2, varscan2
- AHNAK2 | c.17350G>A p.E5784K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV60921552; called by muse, mutect2, varscan2
- ARL4A | c.219C>G p.F73L | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV100775970; called by muse, mutect2, varscan2
- ARL5B | c.366C>G p.I122M | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV66011415; called by muse, mutect2, varscan2
- ATAD3B | c.591C>G p.V197= (on ENST00000308647; = p.V303= on NM_031921.6 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100426664; called by muse, mutect2, varscan2
- ATP8B4 | c.3319C>G p.Q1107E | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV52719295; called by muse, mutect2, varscan2
- ATRN | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53530480; called by muse, mutect2
- ATXN2L | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57372158; called by muse, mutect2, varscan2
- BAZ1A | c.3679G>T p.D1227Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); catalogued as COSV62411077; called by muse, mutect2, varscan2
- BOD1L1 | c.7244A>G p.K2415R | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV50025958; called by muse, mutect2
- BRD7 | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.727); catalogued as COSV67159360; called by muse, mutect2, varscan2
- C16orf78 | c.714G>C p.M238I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV54555589; called by muse, mutect2, varscan2
- C17orf80 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52147652; called by muse, mutect2, varscan2
- C3orf20 | c.1137C>G p.F379L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV53786973; called by muse, mutect2, varscan2
- CAND1 | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs1555183015, COSV73338623; called by muse, mutect2
- CCDC117 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99968969; called by muse, mutect2
- CCDC34 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.403); catalogued as COSV58726439; called by muse, mutect2
- CD55 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV58577464; called by muse, mutect2, varscan2
- CDH7 | c.2107G>C p.D703H | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59885149; called by muse, mutect2, varscan2
- CDK4 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56985790; called by muse, mutect2, varscan2
- CFAP54 | c.5305C>G p.Q1769E | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV61573291; called by muse, mutect2, varscan2
- CHL1 | c.2606G>C p.R869T (on ENST00000397491 / NM_001253387.1; = p.R885T on NM_006614.4) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56593572, COSV56597924; called by muse, mutect2, varscan2
- CHRM3 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1489957274, COSV55094896; called by muse, mutect2, varscan2
- CKMT2 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV54174108; called by muse, mutect2, varscan2
- COASY | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV55899489; called by muse, mutect2, varscan2
- CSN3 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as rs749755921, COSV59243811; called by muse, mutect2, varscan2
- CTC1 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1478316787, COSV59853438; called by muse, mutect2
- CXorf56 | c.448G>A p.E150K (on ENST00000536133 / NM_001170570.2; = p.E164K on NM_022101.4) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57438444, COSV57438726; called by muse, mutect2, varscan2
- CYRIB | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67831405; called by muse, mutect2, varscan2
- DCAF17 | c.1276A>G p.I426V | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV59830734; called by muse, mutect2, varscan2
- DMXL1 | c.4802C>G p.S1601C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs745869189, COSV60716190; called by muse, mutect2, varscan2
- DNAH10 | c.6769C>G p.L2257V (on ENST00000409039; = p.L2196V on NM_207437.3) | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.462); catalogued as rs773625569, COSV101292912; called by muse, mutect2
- DPP3 | c.2059C>G p.L687V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59150226; called by muse, mutect2, varscan2
- DPYS | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59827126; called by muse, mutect2, varscan2
- DYNC1H1 | c.8482G>A p.E2828K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64139119; called by muse, mutect2
- ECM2 | c.389G>C p.R130T | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV60741886; called by muse, mutect2, varscan2
- EFCAB5 | c.1745C>G p.S582* | Nonsense Mutation (SNP) | VAF 22/103 reads (21%) | catalogued as COSV100300893; called by muse, mutect2, varscan2
- ENPEP | c.43C>G p.Q15E | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV54453667, COSV54455928; called by muse, mutect2, varscan2
- EP300 | c.3334C>T p.Q1112* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV54331099; called by muse, mutect2, varscan2
- EPHA7 | c.630G>C p.E210D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV65169834; called by muse, mutect2
- EPM2AIP1 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51620822; called by muse, mutect2
- EPX | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV99836822; called by muse, mutect2, varscan2
- F8 | c.4718C>G p.S1573C | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); catalogued as COSV64275910; called by muse, mutect2, varscan2
- FAF1 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.829); catalogued as COSV65640938; called by muse, mutect2, varscan2
- FBN3 | c.6421T>A p.C2141S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV54465774; called by muse, mutect2
- FBXL5 | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV58012481; called by muse, mutect2, varscan2
- FKBP9 | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54232644; called by muse, mutect2, varscan2
- FOXS1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.665); catalogued as rs757397108, COSV54067232; called by muse, mutect2, varscan2
- GAB1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV53758463; called by muse, mutect2, varscan2
- GPSM2 | c.1641_1644del p.F547Lfs*27 | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | catalogued as COSV51443511; called by mutect2, pindel, varscan2
- GTPBP2 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.024); catalogued as COSV61076790; called by muse, mutect2, varscan2
- GYPA | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs1200831535, COSV51618883, COSV51632369; called by muse, mutect2, varscan2
- GZMM | c.716C>A p.A239D | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV52742572; called by muse, mutect2, varscan2
- HECTD1 | c.4381G>A p.E1461K | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs759243908, COSV67947663; called by muse, mutect2, varscan2
- HPS5 | c.1304G>A p.R435K (on ENST00000349215 / NM_181507.2; = p.R321K on NM_007216.4) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61687702; called by muse, mutect2, varscan2
- HTT | c.5794C>T p.H1932Y | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.977); catalogued as COSV61861201; called by muse, mutect2
- HYDIN | c.4927G>C p.D1643H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs746634444, COSV99993872; called by muse, varscan2
- IP6K3 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV99540238; called by muse, mutect2, varscan2
- IQCN | c.3293C>G p.S1098C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.092); catalogued as COSV100828142, COSV100828456; called by muse, mutect2
- KARS1 | c.207G>C p.E69D | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.079); catalogued as COSV56693213; called by muse, mutect2, varscan2
- KAT6A | c.430C>G p.H144D | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV55908535; called by muse, mutect2
- KATNIP | c.4531C>T p.R1511* | Nonsense Mutation (SNP) | VAF 34/249 reads (14%) | catalogued as rs762066341, COSV99852176; called by muse, mutect2, varscan2
- KDM2B | c.3580C>A p.L1194I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV65642824; called by muse, mutect2, varscan2
- KIF3C | c.2223G>T p.R741S | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV53100555; called by muse, mutect2, varscan2
- KIF3C | c.2222G>T p.R741M | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.496); catalogued as COSV53100571; called by muse, mutect2, varscan2
- KLF17 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV64856665; called by muse, mutect2, varscan2
- KMT2A | c.6168G>A p.W2056* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100630131; called by muse, mutect2, varscan2
- KPNA6 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.196); catalogued as COSV65360620; called by muse, mutect2
- KRT4 | c.453C>G p.F151L | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53408498; called by muse, mutect2, varscan2
- KRT78 | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV58852523; called by muse, mutect2, varscan2
- LARP4B | c.1778C>A p.S593* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as rs1184731342, COSV100295759; called by muse, mutect2, varscan2
- LIX1L | c.712C>G p.Q238E | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100811059, COSV63417169; called by muse, mutect2, varscan2
- LMOD3 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.489); catalogued as COSV70456354; called by muse, mutect2
- LRBA | c.6544C>T p.R2182C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs541771508, COSV63952346; ClinVar: uncertain significance; called by muse, mutect2
- LRIT2 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV60564317; called by muse, mutect2, varscan2
- LRRK1 | c.3348G>A p.M1116I | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52618710; called by muse, mutect2
- LST1 | c.126G>C p.E42D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99279231; called by muse, mutect2
- LTA4H | c.1444G>C p.D482H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV57383267; called by mutect2, varscan2
- MACROH2A2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1391291127, COSV64707015; called by muse, mutect2
- MAGI1 | c.3884G>A p.R1295Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV58318826, COSV58332100; called by muse, mutect2, varscan2
- MAGI1 | c.1360C>T p.Q454* | Nonsense Mutation (SNP) | VAF 4/58 reads (7%) | catalogued as COSV100443351; called by muse, mutect2
- MAS1L | c.377C>A p.S126* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV101009734, COSV65808454; called by muse, mutect2
- MAST2 | c.3523G>C p.E1175Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (1); catalogued as COSV63618583, COSV63619680; called by muse, mutect2
- MDN1 | c.4040-1G>T p.X1347_splice | Splice Site (SNP) | VAF 4/57 reads (7%) | catalogued as COSV101021906; called by muse, mutect2
- MMUT | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV51276624; called by muse, mutect2, varscan2
- MRNIP | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 19/289 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs777642738, COSV52974139; called by muse, mutect2
- MTMR2 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV60580721; called by muse, mutect2
- MTMR3 | c.305C>G p.S102* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100071457, COSV60304548; called by muse, mutect2, varscan2
- MUC13 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.107); catalogued as COSV60700351, COSV60701651; called by muse, mutect2, varscan2
- MUC4 | c.15115G>C p.E5039Q (on ENST00000463781 / NM_018406.7; = p.E803Q on NM_004532.6) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV100204961, COSV57790506; called by muse, mutect2, varscan2
- MYH7 | c.5050G>A p.E1684K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV62517595; called by muse, mutect2
- MYRF | c.2698C>G p.L900V (on ENST00000278836 / NM_001127392.3; = p.L865V on NM_013279.4) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as COSV53891155, COSV99606478; called by muse, mutect2, varscan2
- NINL | c.2049C>A p.H683Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs377678304, COSV54005297; called by muse, mutect2, varscan2
- NSD1 | c.5475G>C p.K1825N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV61779308; called by muse, mutect2, varscan2
- NTAN1 | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV55074976; called by muse, mutect2, varscan2
- NUP93 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV57432102; called by muse, mutect2, varscan2
- OLAH | c.443C>T p.S148L (on ENST00000378228 / NM_001039702.3; = p.S201L on NM_018324.3) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as rs771747283, COSV65493227; called by muse, mutect2, varscan2
- OR4M1 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 19/322 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1287929276, COSV60062454; called by muse, mutect2
- OR6N1 | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs1486094125, COSV100625076, COSV100625323; called by muse, mutect2
- PAX1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745561833, COSV68271758; called by muse, mutect2, varscan2
- PCDHAC2 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53844281, COSV99163508; called by muse, mutect2
- PNKP | c.594G>C p.E198D | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV55589028; called by muse, mutect2, varscan2
- PNO1 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as COSV54562149; called by muse, mutect2, varscan2
- PODXL2 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV61065910; called by muse, mutect2, varscan2
- POLE | c.6253G>A p.E2085K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV57684779; called by muse, mutect2, varscan2
- PRODH2 | c.1141G>A p.G381S (on ENST00000301175; = p.G305S on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56558987; called by muse, mutect2
- PRPSAP1 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as rs775714352, COSV53152917; called by muse, mutect2, varscan2
- PSD | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.407); catalogued as rs754222224, COSV50049755; called by muse, mutect2, varscan2
- PTBP3 | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV52958021; called by muse, mutect2, varscan2
- RAB11FIP1 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as rs754239384, COSV54761859; called by muse, mutect2
- RBL2 | c.2902G>T p.V968F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as rs753303253, COSV50881720; called by muse, mutect2, varscan2
- RBM48 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.784); catalogued as COSV56003133; called by muse, mutect2, varscan2
- RIMBP2 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55478070; called by muse, mutect2, varscan2
- ROBO3 | c.2821G>C p.E941Q | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV67301583; called by muse, mutect2, varscan2
- RTL8A | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.027); catalogued as COSV66188802; called by mutect2, varscan2
- SALL2 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV58102526; called by mutect2, varscan2
- SCG2 | c.66C>G p.I22M | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV59540662, COSV59540890; called by muse, mutect2, varscan2
- SIGLEC10 | c.540G>A p.W180* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100219500; called by muse, mutect2, varscan2
- SLC25A46 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV63506880; called by muse, mutect2, varscan2
- SLC7A9 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50088089; called by muse, mutect2
- SLFNL1 | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV57235018; called by muse, mutect2
- SLITRK4 | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.96); catalogued as COSV62023117, COSV62025035; called by muse, mutect2, varscan2
- SMCHD1 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV55255346, COSV99862766; called by muse, mutect2
- SPAG9 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV56238850; called by muse, mutect2, varscan2
- SPESP1 | c.752G>C p.R251T | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV52992238, COSV52995576; called by muse, mutect2, varscan2
- SRCAP | c.951G>C p.Q317H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV52676357, COSV99351169; called by muse, mutect2, varscan2
- SRCAP | c.8641C>G p.P2881A | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV52670272, COSV52676371; called by muse, mutect2, varscan2
- SRRM2 | c.4742C>T p.S1581L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV57076650; called by muse, mutect2, varscan2
- STIMATE | c.483C>G p.I161M | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61891197; called by muse, mutect2
- SYNE1 | c.16060G>A p.D5354N (on ENST00000367255 / NM_182961.4; = p.D5283N on NM_033071.3) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV55032802; called by muse, mutect2, varscan2
- TFAP2A | c.1123C>G p.Q375E (on ENST00000482890; = p.Q367E on NM_001032280.3) | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV60235667; called by muse, mutect2
- TM9SF4 | c.1026G>C p.M342I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.326); catalogued as rs1210143652, COSV54109036; called by muse, mutect2, varscan2
- TMEM131L | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as COSV99548275; called by muse, mutect2, varscan2
- TNFRSF11A | c.87G>C p.Q29H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54024765; called by muse, mutect2, varscan2
- TRIM71 | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV67471797; called by muse, mutect2
- TRMT112 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV50006768; called by muse, mutect2, varscan2
- TTC14 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs753408175, COSV56012678; called by muse, mutect2, varscan2
- TTLL12 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.078); catalogued as rs1277275363, COSV53356022; called by muse, mutect2, varscan2
- TUBA1A | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV55498261, COSV55498806; called by muse, mutect2, varscan2
- TUBA1A | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.08); catalogued as COSV55498272; called by muse, mutect2
- UBR1 | c.1022G>C p.R341T | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV51932919; called by muse, mutect2
- UHRF1BP1 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51957886; called by muse, mutect2
- VIRMA | c.4399G>A p.D1467N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV52587822; called by muse, mutect2, varscan2
- WDR76 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV51039704; called by muse, mutect2, varscan2
- ZBED9 | c.1324T>C p.F442L | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.216); catalogued as COSV71729589; called by muse, mutect2, varscan2
- ZBTB22 | c.423C>G p.D141E | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV56471106; called by muse, mutect2, varscan2
- ZNF12 | c.1396G>C p.E466Q (on ENST00000405858 / NM_016265.4; = p.E428Q on NM_006956.3) | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV61244913; called by muse, mutect2
- ZNF254 | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV61643621; called by muse, mutect2, varscan2
- ZNF28 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 60/272 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.375); catalogued as COSV60424167; called by muse, mutect2, varscan2
- ZNF33B | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.879); catalogued as rs368178942, COSV63942118; called by muse, mutect2
- ZNF479 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs781924092, COSV100483152, COSV99044415; called by muse, mutect2, varscan2
- ZNF91 | c.3020C>G p.S1007* | Nonsense Mutation (SNP) | VAF 18/131 reads (14%) | catalogued as rs774569855, COSV100323562; called by muse, mutect2, varscan2
- ZSWIM8 | c.4777G>C p.E1593Q (on ENST00000605216 / NM_001242487.2; = p.E1598Q on NM_015037.3) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.986); catalogued as COSV55216178; called by muse, mutect2, varscan2
- AQP7 | c.454G>C p.V152L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, varscan2
- CDKN1B | c.212_225del p.E71Vfs*49 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | called by mutect2, pindel
- GPR179 | c.1945G>A p.E649K (on ENST00000621958; = p.E648K on NM_001004334.4) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHV7-81 | c.210C>G p.F70L | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- SYNRG | c.856C>G p.Q286E | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TUBGCP5 | c.1927G>C p.D643H | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF26 | c.1111C>G p.Q371E | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AP1G1 | c.378C>A p.L126= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV55491992; called by muse, mutect2, varscan2
- ARL11 | c.309C>T p.L103= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV56291623; called by muse, mutect2, varscan2
- B3GAT2 | c.595C>A p.R199= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100017508, COSV57769997, COSV57775208; called by mutect2, varscan2
- BAZ2B | c.5208C>T p.L1736= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV58605014; called by muse, mutect2
- BCL9L | c.2274G>A p.L758= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV52686664; called by muse, mutect2
- CEP192 | c.5232C>T p.G1744= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs781093892, COSV58067234; called by muse, mutect2, varscan2
- CFHR3 | c.45T>C p.C15= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100807840; called by muse, mutect2, varscan2
- CTSV | c.975C>T p.I325= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs754024516, COSV52344091; called by muse, mutect2, varscan2
- CYGB | c.429C>T p.F143= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV53150635; called by muse, mutect2, varscan2
- DNAH5 | c.12048C>T p.I4016= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs375133229, COSV54237982; called by muse, mutect2, varscan2
- EOGT | c.651C>G p.L217= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV55152348; called by muse, mutect2, varscan2
- FLRT1 | c.1683G>T p.V561= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV55363463; called by muse, mutect2, varscan2
- GDF5 | c.501C>T p.I167= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV65502273; called by muse, mutect2, varscan2
- GIGYF2 | c.3372C>G p.L1124= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV65251324; called by muse, mutect2, varscan2
- HMGXB4 | c.525C>T p.L175= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs1337001147, COSV53334879; called by muse, mutect2, varscan2
- HOXB8 | c.570C>T p.V190= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as COSV53311007, COSV99494047; called by muse, mutect2, varscan2
- HTR1E | c.1017C>T p.I339= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV59509041; called by muse, mutect2, varscan2
- IFNA21 | c.420C>T p.I140= | Silent (SNP) | VAF 94/361 reads (26%) | catalogued as COSV66518563; called by muse, mutect2, varscan2
- IGFN1 | c.1650G>A p.V550= (on ENST00000295591 / NM_001367841.1; = p.V3007= on NM_001164586.2) | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV55177646; called by muse, mutect2, varscan2
- IL24 | c.603G>A p.Q201= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as rs774866776, COSV54321046; called by muse, mutect2, varscan2
- ITFG1 | c.297G>A p.L99= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV57751726; called by muse, mutect2
- LATS2 | c.141G>A p.L47= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV66877489; called by muse, mutect2, varscan2
- LCK | c.1164C>T p.L388= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV60741476; called by muse, mutect2, varscan2
- LMOD3 | c.1014G>A p.E338= | Silent (SNP) | VAF 27/268 reads (10%) | catalogued as COSV70456344; called by muse, mutect2
- LMTK3 | c.234G>A p.E78= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs1179931145, COSV99541300; called by muse, mutect2
- MINK1 | c.2211C>T p.L737= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV61791320; called by muse, mutect2, varscan2
- NOS3 | c.993C>T p.Y331= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs370490675; called by muse, mutect2, varscan2
- NPFFR2 | c.447C>T p.I149= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV58148707, COSV58151688; called by muse, mutect2
- NYNRIN | c.3825C>T p.L1275= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs780717857, COSV66841928; called by muse, mutect2, varscan2
- PKP1 | c.1677C>T p.S559= | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as COSV55823146; called by muse, mutect2
- PNLIPRP1 | c.1032C>T p.F344= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV62612509; called by muse, mutect2, varscan2
- PPT2 | c.723C>T p.F241= | Silent (SNP) | VAF 40/329 reads (12%) | catalogued as COSV61354898; called by muse, mutect2, varscan2
- PRKRIP1 | c.114C>G p.L38= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV61350303; called by muse, mutect2, varscan2
- PRPS1L1 | c.489G>A p.K163= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV72649940; called by muse, mutect2, varscan2
- PTPRS | c.5241G>A p.Q1747= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV53627411; called by muse, mutect2, varscan2
- PYGB | c.2130C>T p.F710= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV53820443; called by muse, mutect2, varscan2
- RAD21 | c.606G>C p.L202= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as COSV52061078; called by muse, mutect2, varscan2
- RAD54L2 | c.966C>T p.L322= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV56579925; called by muse, mutect2
- RAP1GAP2 | c.417C>T p.L139= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV54582293, COSV54590931; called by muse, mutect2, varscan2
- RYR2 | c.7338C>T p.A2446= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV63697688, COSV63705238; called by muse, mutect2, varscan2
- S100A9 | c.156G>A p.E52= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV64199784; called by muse, mutect2, varscan2
- SERPINI2 | c.915G>A p.L305= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV52987450; called by muse, mutect2, varscan2
- SLC39A2 | c.585C>T p.L195= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100068754; called by muse, mutect2
- SLC4A2 | c.3273G>A p.V1091= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV52541006; called by muse, mutect2, varscan2
- SORT1 | c.1764C>T p.F588= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as rs1224400776, COSV56668000; called by muse, mutect2
- SP7 | c.894C>T p.I298= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV58191300; called by muse, mutect2, varscan2
- ST8SIA5 | c.913C>T p.L305= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV59333503; called by muse, mutect2
- STK40 | c.384G>C p.R128= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as COSV63735938; called by muse, mutect2
- TAF4B | c.1735C>T p.L579= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV52306791; called by muse, mutect2, varscan2
- TBC1D1 | c.2232C>G p.L744= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV54722789; called by muse, mutect2, varscan2
- THAP12 | c.2004G>T p.L668= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV52611551; called by muse, mutect2, varscan2
- TLL1 | c.735G>A p.V245= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV50303605; called by muse, mutect2
- TMEM202 | c.174G>A p.T58= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs148667101; called by muse, mutect2, varscan2
- TNNC2 | c.105C>T p.I35= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV65332971; called by muse, mutect2, varscan2
- TNNT2 | c.327G>C p.L109= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as COSV52663805; called by muse, mutect2, varscan2
- UBA7 | c.2616G>A p.V872= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV60967643; called by muse, mutect2, varscan2
- WAC | c.1470G>T p.V490= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV61568387; called by muse, mutect2, varscan2
- WDR88 | c.561C>T p.T187= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV63452007; called by muse, mutect2, varscan2
- WEE2 | c.351G>A p.L117= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV66879489; called by muse, mutect2, varscan2
- ZAP70 | c.219C>T p.G73= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs772581697, COSV99386033; called by muse, varscan2
- ZFYVE26 | c.5928G>A p.T1976= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs780544451, COSV61330828, COSV61331665; called by muse, mutect2, varscan2
- ZNF324B | c.474C>T p.I158= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV60742506; called by muse, mutect2, varscan2
- ZNF846 | c.564G>A p.Q188= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV67412263; called by muse, mutect2, varscan2
- AMFR | c.*233G>C | 3'UTR (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99316278; called by muse, mutect2, varscan2
- DST | c.4296+4139G>T | Intron (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99760681; called by muse, mutect2, varscan2
- OSGIN1 | n.1825C>T | RNA (SNP) | VAF 6/27 reads (22%) | catalogued as COSV59421991; called by muse, mutect2
- RUFY3 | c.-1C>T | 5'UTR (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99888144; called by muse, mutect2, varscan2
- TANGO2 | c.-39-3547C>T | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- TRNAU1AP | chr1:28580945 G>C | 3'Flank (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
